CCDI case PBCGZG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Skin.
https://portal.gdc.cancer.gov/cases/7a7e9e00-fad6-490a-bdff-f4a2ff2af2bb

Demographics
Sex at birth: female.

Diagnoses (1)
1. Malignant tumor, spindle cell type: ICD-O-3 morphology code: 8004/3; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 0.4 years (158 days).

Biospecimens (3 samples)
- Sample 0DU1VR: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DU1W6: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DU1X7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
